Gene-level copy-number profile of tumor specimen C3L-08660-03 from CPTAC case C3L-08660, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 78.4 years (28,643 days).
Specimen C3L-08660-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dfa3389a-a3e0-4422-bbfd-5eb5600178e2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08660-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/fce63f9c-5f88-413f-9449-0d54fb37d060

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 912; copy number 3: 18,161; copy number 4: 33,711; copy number 5: 4,144; copy number 6: 1,172; copy number 8: 49; copy number 10: 44; copy number 11: 24; copy number 13: 64; copy number 16: 1; copy number 17: 55; copy number 18: 23; copy number 21: 40.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 251 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:162,322,188–162,323,907, 1 gene, copy number 16: MTHFD2P4.
- chr4:163,471,095–163,520,539, 2 genes, copy number 18: TKTL2, TMA16.
- chr9:16,917,511–19,894,856, 34 genes, copy number 10–21: AL162725.2, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11, ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1, SAXO1, AL356000.1, RRAGA, HAUS6, SCARNA8, RNU6-264P, Y_RNA, PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2.
- chr10:71,964,395–73,496,024, 55 genes, copy number 13 (within-gene range 2–13): CHST3, AC022392.1, SPOCK2, ASCC1, AL607035.1, RPL15P14, ANAPC16, Y_RNA, DDIT4, DDIT4-AS1, DNAJB12, MICU1, RNU6-805P, AC091769.1, SNX19P4, AL513185.1, AL513185.2, RN7SL840P, HMGN2P34, AL513185.3, Y_RNA, MCU, MIR4676, AC016542.3, AC016542.2, AC016542.1, OIT3, NPM1P24, PLA2G12B, RPL17P50, P4HA1, AL731563.1, AL731563.2, Y_RNA, AL731563.3, NUDT13, AC016394.1, SNORA11F, ECD, FAM149B1, DNAJC9, Y_RNA, EIF4A2P2, AC016394.2, DNAJC9-AS1, MRPS16, DNAJC9-AS1, CFAP70, RNU6-833P, Y_RNA, ANXA7, AL512656.1, RPL26P6, MSS51, PPP3CB.
- chr10:73,674,287–75,408,982, 57 genes, copy number 10–13 (within-gene range 2–13): AGAP5, BMS1P4-AGAP5, BMS1P4, AC022400.4, RNA5SP320, BMS1P4, GLUD1P3, DUSP8P5, AC022400.3, AC022400.6, SEC24C, AC022400.7, FUT11, CHCHD1, ZSWIM8, AC022400.8, ZSWIM8-AS1, AC022400.5, NDST2, CAMK2G, AC022400.1, AC022400.2, PLAU, C10orf55, VCL, AL596247.1, AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2.
- chr18:22,699,481–27,595,164, 90 genes, copy number 17–21 (broad region; genes not listed).
- chr20:52,858,338–53,544,725, 12 genes, copy number 11: AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
